Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A9WJ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A9WJ-01A (Primary Tumor).

[page 1 of 2]
PROSTATE AND ILIAC/OBTURATOR LYMPH NODES; RADICAL PROSTATECTOMY:

TUMOR PROCUREMENT:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA WITH SMALL FOCI OF MUCINOUS DIFFERENTIATION

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 4 = 8

TERTIARY PATTERN 3

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

1: ___%

2: ___%

3: ___5%

4: ___95%

5: ___%

Per TSS, mucinous = 7%

TUMOR LOCATION

ANTERIOR

RIGHT

LEFT

LATERAL

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT

NON-FOCAL

SITE OF EXTRA-PROSTATIC EXTENSION

LATERAL

RIGHT

LEFT

SEMINAL VESICAL INVASION

PRESENT

LEFT

SURGICAL MARGINS

INVOLVED BY INVASIVE CARCINOMA

APEX

MID

LEFT VAS DEFERENS

NATURE OF POSITIVE MARGINS

INDETERMINATE

EXTENT OF POSITIVE MARGINS

MULTIFOCAL

MILLIMETRIC EXTENT OF POSITIVE MARGINS: _NOT REPORTED

GLEASON GRADE OF CARCINOMA PRESENT AT THE POSITIVE MARGINS

NOT REPORTED

LYMPHOVASCULAR INVASION

PRESENT

PERINEURAL INVASION

PRESENT

TUMOR VOLUME

PROPORTION OF PROSTATE INVOLVED BY CARCINOMA: _30-40%

TREATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

LYMPH NODES

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Prostate NOS C61.9

W 5/19/14

[page 2 of 2]
RIGHT OBTURATOR

NUMBER OF NODES IDENTIFIED: 6

NUMBER OF NODES INVOLVED BY METASTASIS: 0

LEFT OBTURATOR

NUMBER OF NODES IDENTIFIED: 4

NUMBER OF NODES INVOLVED BY METASTASIS: 1

DIAMETER OF LARGEST LYMPH NODE METASTASIS: NOT REPORTED

ADDITIONAL PATHOLOGIC FINDINGS

HIGH-GRADE PROSTATIC INTRA-EPITHELIAL NEOPLASIA

BASAL CELL HYPERPLASIA

PATHOLOGICAL STAGING

pT3b

pN1

pMX

Source: NCI Genomic Data Commons file 1465736f-c86d-4b38-9712-8e3b0285b6fc (TCGA-YL-A9WJ.EC025153-CB9C-4683-82B4-985AAA9E80AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).